Somatic mutation profile of tumor specimen TCGA-HD-A6I0-01A (aliquot TCGA-HD-A6I0-01A-11D-A31L-08) from TCGA case TCGA-HD-A6I0, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 56.1 years (20,491 days).
Specimen TCGA-HD-A6I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67f949ac-cb08-4758-8839-d9dbc3a82c6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-A6I0-10A (Blood Derived Normal), aliquot TCGA-HD-A6I0-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f90e8ba5-5cb2-4925-8aa2-64703043c81a

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 15, Frame Shift Del 3, Frame Shift Ins 2, RNA 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBA | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121908311, CM940812, BM1387467, COSV100516393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AKAP6 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs539925484, COSV55207514; called by muse, mutect2, varscan2
- AL441992.2 | c.1463A>G p.H488R | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1248374342, COSV100223713; called by muse, mutect2, varscan2
- ALOX15B | c.2020G>A p.V674I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs201702180, COSV66480213; called by muse, mutect2, varscan2
- ANKRD17 | c.3455C>A p.T1152K | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100429525; called by muse, mutect2, varscan2
- ANO2 | c.2265C>A p.F755L (on ENST00000356134 / NM_001278597.3; = p.F759L on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100501468; called by muse, mutect2, varscan2
- ATP10A | c.4390G>C p.D1464H | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100791376; called by muse, mutect2, varscan2
- COL1A2 | c.2905G>A p.V969M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs765448220, COSV51955294; called by muse, mutect2, varscan2
- DENND5B | c.3530T>A p.I1177N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100171730; called by muse, mutect2, varscan2
- DEPDC1 | c.2156A>C p.Y719S (on ENST00000456315 / NM_001114120.3; = p.Y435S on NM_017779.6) | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100920393; called by muse, mutect2, varscan2
- DEPDC5 | c.2975C>T p.S992L (on ENST00000400246; = p.S1061L on NM_014662.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV99835814; called by muse, mutect2, varscan2
- DGKZ | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs758235923, COSV58998065; called by muse, varscan2
- ELOA2 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs766103603, COSV55304399; called by muse, mutect2, varscan2
- EMILIN2 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV99598666; called by muse, mutect2, varscan2
- EPHB1 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV67654085; called by muse, mutect2, varscan2
- FLT1 | c.3895C>A p.H1299N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV56718016, COSV99163436; called by muse, mutect2, varscan2
- FOS | c.119T>C p.M40T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as COSV100338510; called by muse, mutect2, varscan2
- GIGYF2 | c.3436C>G p.L1146V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs1445305113, COSV101004489, COSV65247268; called by muse, mutect2, varscan2
- HEATR5B | c.4729G>A p.A1577T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs781598789, COSV99249711; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.569G>C p.R190T (on ENST00000354667 / NM_031243.3; = p.R178T on NM_002137.4) | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV100522976; called by muse, mutect2, varscan2
- IRF2BP1 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100138929; called by muse, mutect2, varscan2
- ITGB1 | c.1110G>C p.L370F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100171795, COSV56481434; called by muse, mutect2, varscan2
- JMJD1C | c.4831G>A p.D1611N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV100550353; called by muse, mutect2, varscan2
- KCNA10 | c.461C>A p.P154Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871451; called by muse, mutect2, varscan2
- KCNK9 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs750174835, COSV100271210; called by muse, mutect2, varscan2
- KCTD19 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.094); catalogued as rs765316967, COSV100431057; called by muse, mutect2, varscan2
- KCTD8 | c.1180A>G p.K394E | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV63585254, COSV63588444; called by muse, mutect2, varscan2
- KLHL1 | c.338A>T p.Q113L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.006); catalogued as COSV100917603; called by muse, mutect2, varscan2
- LRP10 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100612414; called by muse, mutect2, varscan2
- LRRC8A | c.1241A>T p.D414V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs752328296, COSV99396720; called by muse, mutect2, varscan2
- MAP2K1 | c.939G>T p.L313F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100198881; called by muse, mutect2, varscan2
- MGA | c.7304G>A p.R2435Q (on ENST00000219905 / NM_001164273.1; = p.R2226Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54951059, COSV54964414; called by muse, mutect2, varscan2
- NKG7 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99389912; called by muse, mutect2, varscan2
- NKX6-2 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV63973682; called by muse, mutect2, varscan2
- NOTCH1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1341448592, COSV53031725, COSV53054024; called by muse, mutect2, varscan2
- POMGNT2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143806708; called by muse, mutect2, varscan2
- PTPRO | c.1731G>A p.W577* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99841015; called by muse, mutect2, varscan2
- PTPRT | c.4240C>T p.R1414C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746059787, COSV61986705; ClinVar: benign; called by muse, mutect2, varscan2
- RPS6KA1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV65176550; called by muse, mutect2, varscan2
- SCML1 | c.971G>A p.G324E (on ENST00000380041 / NM_001037540.3; = p.G297E on NM_006746.6) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101193955; called by muse, mutect2, varscan2
- SELENOT | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1281748032, COSV101517709; called by mutect2, varscan2
- SLC6A13 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs141229734; called by muse, mutect2, varscan2
- SORBS1 | c.2032G>A p.E678K (on ENST00000361941 / NM_001034954.2; = p.E384K on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53366665; called by muse, mutect2, varscan2
- SORD | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs1338835191, COSV51044481; called by muse, mutect2, varscan2
- SPACA7 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs376712879; called by muse, mutect2, varscan2
- TMEM132A | c.1894G>A p.D632N (on ENST00000453848 / NM_178031.3; = p.D633N on NM_017870.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs767469363, COSV99136026; called by muse, mutect2, varscan2
- TOR1AIP2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs145359130; called by muse, mutect2, varscan2
- TTF2 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs200362905, COSV101037614; called by muse, mutect2, varscan2
- USP29 | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs878972912, COSV54143792, COSV54144866; called by muse, mutect2, varscan2
- USP54 | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766804729, COSV60444311, COSV60447278; called by muse, mutect2, varscan2
- ZDHHC17 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.034); catalogued as COSV100602172; called by muse, varscan2
- ZNF48 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs770357279, COSV100197981, COSV100198174; called by muse, mutect2, varscan2
- ZNF808 | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs1333789699, COSV63119795; called by muse, mutect2, varscan2
- COA7 | c.9_12del p.M4Wfs*54 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | called by mutect2, pindel, varscan2
- FAT1 | c.10941_10947del p.A3648Sfs*24 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- FAT1 | c.1639_1640dup p.R548Tfs*16 | Frame Shift Ins (INS) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- FOSL2 | c.579_588del p.I193Mfs*24 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, pindel, varscan2
- RPS6KA1 | c.1289_1290dup p.E431Lfs*46 | Frame Shift Ins (INS) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- ARG2 | c.712C>T p.L238= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99373792; called by muse, mutect2
- ATAD2 | c.2130A>G p.Q710= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV99784937; called by muse, mutect2, varscan2
- CCDC38 | c.285G>A p.P95= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs376813830, COSV100717729; called by muse, mutect2, varscan2
- CLIP1 | c.381G>A p.K127= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV100211973; called by muse, mutect2, varscan2
- DENND5B | c.3822G>T p.V1274= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100171726; called by muse, mutect2, varscan2
- JPH3 | c.909C>T p.S303= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs751131621, COSV99413649; called by muse, mutect2, varscan2
- MGAM | c.3237G>A p.E1079= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as COSV72074204; called by muse, mutect2, varscan2
- MUC7 | c.342G>A p.V114= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100512338; called by muse, mutect2, varscan2
- PCDHA10 | c.1179G>A p.P393= | Silent (SNP) | VAF 48/194 reads (25%) | catalogued as rs148283153, COSV100246875, COSV56486673; called by muse, mutect2, varscan2
- PLEKHM1 | c.1833C>T p.D611= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs199719858, COSV101378794; called by muse, mutect2, varscan2
- PLXNA4 | c.5475C>T p.S1825= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs114567124, COSV58137613; called by muse, mutect2, varscan2
- RRBP1 | c.2715C>T p.A905= (on ENST00000377813 / NM_001365613.2; = p.A472= on NM_004587.3) | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs143484132; called by muse, mutect2, varscan2
- SDK2 | c.1929G>A p.V643= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as COSV101167907, COSV101168531; called by muse, mutect2, varscan2
- SLC26A8 | c.2244C>T p.A748= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100839529; called by muse, mutect2, varscan2
- SYPL2 | c.387C>T p.T129= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100881560; called by muse, mutect2, varscan2
- DST | c.4297-3636G>T | Intron (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99757882; called by muse, mutect2, varscan2
- SNORD115-35 | n.9G>A | RNA (SNP) | VAF 59/313 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.3680G>C | RNA (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100022718; called by muse, mutect2
